Surgical pathology report (de-identified scan), TCGA case TCGA-AO-A124, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site MSKCC, specimen TCGA-AO-A124-01A (Primary Tumor).

[page 1 of 9]
Clinical Diagnosis and History:
y/o female with palpable right breast mass, (+) core - IDC.
Left breast calcification.

Specimens Submitted:

- 1: SP: Sentinel node #1, level 1, left axilla (fs)
- 2: SP: Sentinel node #2, level 1, left axilla (fs)
- 3: SP: Sentinel node #3, level 1, left axilla (fs)
- 4: SP: Lt. breast axillary contents lvls 12 w/tags
- 5: SP: Sentinel node #1, level 1, right axilla (fs)
- 6: SP: Sentinel node #2, level 1, right axilla (fs)
- 7: SP: Sentinel node #3, level 1, right axilla (fs)
- 8: SP: Sentinel node #4, level 1, right axilla (fs)
- 9: SP: Rt. breast axillary contents lvls 12 w/tags
- 10: SP: Additional lymph nodes lt. axilla
- 11: SP: Additional lymph nodes rt. axilla

DIAGNOSIS:

- 1) SENTINEL LYMPH NODE #1, LEVEL I, LEFT AXILLA; BIOPSY:
- METASTATIC CARCINOMA INVOLVING ONE OF ONE LYMPH NODE (1/1).
- THE TUMOR DEPOSIT MEASURES LESS THAN 1 MM AND IS CONFINED TO THE LYMPH NODE.
- 2) SENTINEL LYMPH NODE #2, LEVEL I, LEFT AXILLA; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- 3) SENTINEL LYMPH NODE #3, LEVEL I, LEFT AXILLA; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- 4) BREAST, LEFT AND AXILLARY CONTENTS; RESECTION:
- INVASIVE DUCTAL CARCINOMA, MIXED MUCINOUS (MUCINOUS NOS) TYPE, HISTOLOGIC GRADE III/III (SLIGHT OR NO TUBULE FORMATION), NUCLEAR GRADE III/III (MARKED VARIATION IN SIZE AND SHAPE), MEASURING 2.3 CM IN LARGEST DIMENSION MICROSCOPICALLY.
- A SECOND FOCUS OF IN SITU AND INVASIVE DUCTAL CARCINOMA MEASURING 0.9 CM IS PRESENT IN THE CENTRAL AREA OF THE BREAST.
- DUCTAL CARCINOMA IN SITU (DCIS) IS ALSO IDENTIFIED, SOLID TYPE WITH HIGH NUCLEAR GRADE AND EXTENSIVE NECROSIS. THE DCIS CONSTITUTES <= 25% OF THE TOTAL TUMOR MASS, AND IS PRESENT ADMIXED WITH AND AWAY FROM THE INVASIVE COMPONENT.

** Continued on next page **

PATH
REPORT
11

1CA-0-3

carcinoma, infiltrating duct and mucinous

8523/3

Site breast, Nos C50.9 lw 10/22/11

HPA/Discrepancy		
Case is (re)classified		

[page 2 of 9]
2

- THE INVASIVE CARCINOMA IS LOCATED IN THE UPPER OUTER QUADRANT AND LOWER OUTER QUADRANT. THE DCIS IS LOCATED IN THE UPPER OUTER QUADRANT AND LOWER OUTER QUADRANT.
- NO INVOLVEMENT OF THE NIPPLE BY EITHER IN SITU OR INVASIVE CARCINOMA IS IDENTIFIED.
- CALCIFICATIONS ARE PRESENT IN THE IN SITU CARCINOMA.
- NO VASCULAR INVASION IS NOTED.
- NO INVOLVEMENT OF THE SURGICAL MARGINS BY EITHER INVASIVE OR IN SITU CARCINOMA IS IDENTIFIED.
- NO SKIN INVOLVEMENT BY CARCINOMA IS IDENTIFIED.

- THE NON-NEOPLASTIC BREAST TISSUE SHOWS MARKED SECRETORY CHANGES.
- THE LYMPH NODE STATUS IS AS FOLLOWS (EXPRESSED AS THE NUMBER OF POSITIVE LYMPH NODES IN RELATION TO THE TOTAL NUMBER OF LYMPH NODES EXAMINED): LEVEL I: 0/8 AND LEVEL II: 0/4.
- RESULTS OF SPECIAL STAINS (ER, PR, HER2-NEU) WILL BE REPORTED AS AN ADDENDUM.

- 5) SENTINEL LYMPH NODE #1, LEVEL I, RIGHT AXILLA; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- DEEPER LEVEL RECUTS AND SPECIAL STAINS HAVE BEEN ORDERED. THE RESULTS WILL BE REPORTED IN AN ADDENDUM.
- 6) SENTINEL LYMPH NODE #2, LEVEL I, RIGHT AXILLA; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- DEEPER LEVEL RECUTS AND SPECIAL STAINS HAVE BEEN ORDERED. THE RESULTS WILL BE REPORTED IN AN ADDENDUM.
- 7) SENTINEL LYMPH NODE #3, LEVEL I, RIGHT AXILLA; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- DEEPER LEVEL RECUTS AND SPECIAL STAINS HAVE BEEN ORDERED. THE RESULTS WILL BE REPORTED IN AN ADDENDUM.
- 8) SENTINEL LYMPH NODE #4, LEVEL I, RIGHT AXILLA; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- DEEPER LEVEL RECUTS AND SPECIAL STAINS HAVE BEEN ORDERED. THE RESULTS WILL BE REPORTED IN AN ADDENDUM.
- 9) BREAST, RIGHT AND AXILLARY CONTENTS; RESECTION:
- INVASIVE DUCTAL CARCINOMA, NOS TYPE, HISTOLOGIC GRADE III/III (SLIGHT OR NO TUBULE FORMATION), NUCLEAR GRADE III/III (MARKED VARIATION IN SIZE AND SHAPE), MEASURING 4.6 CM IN LARGEST DIMENSION GROSSLY.
- THE INVASIVE CARCINOMA IS LOCATED IN THE UPPER OUTER QUADRANT AND LOWER OUTER QUADRANT.
- NO INVOLVEMENT OF THE NIPPLE BY EITHER IN SITU OR INVASIVE CARCINOMA IS IDENTIFIED.
- NO CALCIFICATIONS ARE IDENTIFIED.
- NO VASCULAR INVASION IS NOTED.
- NO INVOLVEMENT OF THE SURGICAL MARGINS BY EITHER INVASIVE OR IN SITU CARCINOMA IS IDENTIFIED.
- NO SKIN INVOLVEMENT BY CARCINOMA IS IDENTIFIED.

PATH
REPORT

** Continued on next page **

[page 3 of 9]
- 3
- THE NON-NEOPLASTIC BREAST TISSUE SHOWS MARKED SECRETORY CHANGES.
- THE LYMPH NODE STATUS IS AS FOLLOWS (EXPRESSED AS THE NUMBER OF POSITIVE LYMPH NODES IN RELATION TO THE TOTAL NUMBER OF LYMPH NODES EXAMINED): LEVEL I: 0/8 AND LEVEL II: 0/1.
- RESULTS OF SPECIAL STAINS (ER, PR, HER2-NEU) WILL BE REPORTED AS AN ADDENDUM.

- 10) LYMPH NODE, "ADDITIONAL", LEFT AXILLA; RESECTION:
- METASTATIC CARCINOMA INVOLVING TWO OUT OF FOUR LYMPH NODES (2/4) MEASURING 1 MM AND 2.2 MM IN DIMENSION, WITHOUT EXTRANODAL EXTENSION.
- 11) LYMPH NODE, "ADDITIONAL", RIGHT AXILLA; RESECTION:
- FIVE BENIGN LYMPH NODES (0/5).

** Report Electronically Signed Out **

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Stain/Procedure Name	Result	Comment
ESTROGEN RECEPTOR	NEGATIVE	
PROGESTERONE RECEPTOR	NEGATIVE	
HER2-C	POSITIVE	
IMMUNO RECUT		
NEGATIVE CONTROL		
NEGATIVE CONTROL FOR HER2		
AE1:AE3	NEGATIVE	
KERATIN (CAM5.2)	NEGATIVE	
RECUT ADDITIONAL HE		
IMMUNO RECUT		
NEGATIVE CONTROL		
AE1:AE3	NEGATIVE	
KERATIN (CAM5.2)	NEGATIVE	
RECUT ADDITIONAL HE		
IMMUNO RECUT		
NEGATIVE CONTROL		
AE1:AE3	NEGATIVE	
KERATIN (CAM5.2)	NEGATIVE	
RECUT ADDITIONAL HE		
IMMUNO RECUT		
NEGATIVE CONTROL		
AE1:AE3	NEGATIVE	
KERATIN (CAM5.2)	NEGATIVE	
RECUT ADDITIONAL HE		

PATH
REPORT
11

** Continued on next page **

[page 4 of 9]
4

IMMUNO RECUT
NEGATIVE CONTROL
AE1:AE3
KERATIN (CAM5.2)
RECUT ADDITIONAL HE
IMMUNO RECUT
NEGATIVE CONTROL
ESTROGEN RECEPTOR
PROGESTERONE RECEPTOR
HER2-C
IMMUNO RECUT
NEGATIVE CONTROL
NEGATIVE CONTROL FOR HER2

NEGATIVE
NEGATIVE
NEGATIVE
NEGATIVE
NEGATIVE
NEGATIVE

Gross Description:

1) The specimen is received fresh for frozen section, labeled "Sentinel Node #1 Level 1 Left Axilla". It consists of one lymph node measuring 2.3 cm. It is bisected and entirely frozen in two cassettes.

Summary of Sections:

FSC - frozen section control

2) The specimen is received fresh for frozen section, labeled "Sentinel Node #2 Level 1 Left Axilla". It consists of one lymph node measuring 2 cm. It is bisected and entirely frozen in one cassette.

Summary of Sections:

FSC - frozen section control

3) The specimen is received fresh for frozen section, labeled "Sentinel Node #3 Level 1 Left Axilla". It consists of one lymph node measuring 1.1 cm. It is bisected and entirely submitted in one cassette.

Summary of Sections:

FSC - frozen section control

4) The specimen is received fresh, labeled "Left Breast and Axillary Contents Levels 1 and 2". It consists of a breast measuring 23 x 20 x 5 cm with an attached axillary tail measuring approximately 7 x 5 x 2 cm. An ellipse of skin measuring 27 x 15 cm is attached to the specimen. The nipple and areola measure respectively, 1.5 and 4.5 cm in diameter and are located in the

PATH
REPORT
11

** Continued on next page **

[page 5 of 9]
5

middle of the skin ellipse. Sectioning reveals an indurated nodule located at the junction of the upper outer and lower outer quadrants, measuring 2 x 1.5 x 1.5 cm. This nodule is dyed blue. There is an extension of granular, firm tissue measuring approximately 4 x 2 x 2 cm, and extending toward the axillary tail. In this granular area, there is a hemorrhagic cavity, probably corresponding to a previous biopsy site. The indurated area and the granular area are located at least 1 to 2 cm away from the nearest deep inked margin. There is a second indurated area measuring less than 1 cm in diameter, clearly separate from the first, and located approximately 3 cm deep to the nipple. This area is sampled separately. The specimen is representatively sampled in a total of twenty two cassettes.

Summary of Sections:

UO - upper outer quadrant
LO - lower outer quadrant
UI - upper inner quadrant
LI - lower inner quadrant
MAR - margin
IND - indurated area
GRAN - granular area
BN - little nodule below nipple
N - nipple
ONE - level 1 lymph node
TWO - level 2 lymph node
TWOB - level 2 lymph node bisected

5) The specimen is received fresh for frozen section, labeled "Sentinel Node #1 Level 1 Right Axilla". It consists of one lymph node measuring 1 cm. It is bisected and entirely frozen in one cassette.

Summary of Sections:

FSC - frozen section control

6) The specimen is received fresh for frozen section, labeled "Sentinel Node #2 Level 1 Right Axilla". It consists of one lymph node measuring 1 cm in diameter. It is bisected and entirely frozen in one cassette.

Summary of Sections:

FSC - frozen section control

7) The specimen is received fresh for frozen section, labeled "Sentinel Node #3 Level 1 Right Axilla". It consists of one lymph node measuring 1.5 cm. It is bisected and entirely frozen in one cassette.

PATH
REPORT
11

** Continued on next page **

[page 6 of 9]
Summary of Sections:

FSC - frozen section control

8) The specimen is received fresh for frozen section, labeled "Sentinel Node #4 Level 1 Right Axilla". It consists of one lymph node measuring 2 cm. It is bisected and entirely submitted in two cassettes.

Summary of Sections:

FSC - frozen section control

9) The specimen is received fresh, labeled "Right Breast With Axillary Contents Levels 1 and 2". It consists of a breast measuring 28 x 20 x 5.5 cm approximately with an attached axillary process measuring approximately 8 x 5 x 3 cm. An ellipse of skin measuring 26.5 x 15 cm is identified. The nipple and areola measure respectively, 2 and 4.5 cm in diameter. Sectioning reveals a rounded, well-demarcated lesion measuring 4.6 x 4.3 x 3.5 cm. This lesion is located at the junction of the upper outer and the lower outer quadrant. It is located at least 2 cm away from the nearest deep margin. The remaining breast tissue is unremarkable. The specimen is representatively submitted in a total of twenty two cassettes.

Summary of Sections:

UI - upper inner quadrant
LI - lower inner quadrant
UO - upper outer quadrant
LO - lower outer quadrant
M - deep margin near the tumor
N - nipple
T - tumor
ONE - level 1 lymph nodes
TWO - level 2 lymph nodes

10) The specimen is received in formalin, labeled "Additional Lymph Nodes Left Axilla". It consists of several fragments of fibrofatty soft tissue forming an aggregate measuring 2.5 x 1.5 x 1 cm. The specimen is entirely submitted in two cassettes.

Summary of Sections:

U - undesignated

PATH
REPORT
11

** Continued on next page **

[page 7 of 9]
11) The specimen is received in formalin, labeled "Additional Lymph Nodes Right Axilla". It consists of several fragments of fibrofatty soft tissue forming an aggregate measuring 3 x 2.5 x 1.5 cm. The specimen is entirely submitted in three cassettes.

Summary of Sections:
U - undesignated

Summary of Sections:

Part	Sect. Site	Blocks	Pieces	All
1	FSC	2	M	Y
2	FSC	1	M	Y
3	FSC	1	M	Y
4	BN	1	1	N
	GRAN	2	M	
	IND	2	M	
	LI	2	M	
	LO	2	M	
	MAR	1	1	
	N	1	1	
	ONE	4	M	
	TWO	2	M	
	TWOB	1	M	
	UI	2	M	
	UO	2	M	
5	FSC	1	M	Y
6	FSC	1	1	Y
7	FSC	1	M	Y
8	FSC	2	M	Y
9	LI	2	M	N
	LO	2	M	
	M	1	1	
	N	1	1	
	ONE	4	M	
	T	3	M	
	TWO	5	M	
	UI	2	M	
	UO	2	M	
10	U	2	M	Y
11	U	3	M	Y

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: POSITIVE FOR MICROMETASTATIC CARCINOMA.
PERMANENT DIAGNOSIS: SAME
- 2) FROZEN SECTION DIAGNOSIS: BENIGN LYMPH NODE.
PERMANENT DIAGNOSIS: SAME
- 3) FROZEN SECTION DIAGNOSIS: BENIGN LYMPH NODE.
PERMANENT DIAGNOSIS: SAME

** Continued on next page **

PATH
REPORT
11

[page 8 of 9]
- 5) FROZEN SECTION DIAGNOSIS: NO TUMOR IDENTIFIED.
PERMANENT DIAGNOSIS: SAME
- 6) FROZEN SECTION DIAGNOSIS: NO TUMOR IDENTIFIED.
PERMANENT DIAGNOSIS: SAME
- 7) FROZEN SECTION DIAGNOSIS: NO TUMOR IDENTIFIED.
PERMANENT DIAGNOSIS: SAME
- 8A) FROZEN SECTION DIAGNOSIS: NEGATIVE.
PERMANENT DIAGNOSIS: SAME
- 8B) FROZEN SECTION DIAGNOSIS: NEGATIVE.
PERMANENT DIAGNOSIS: SAME

ADDENDUM:

** SIGNED OUT *

ADDENDUM REPORT

SITE: SENTINEL LYMPH NODES, LEVEL 1, RIGHT AXILLA, BIOPSIES:
PARTS #5,6,7,8.

ADDITIONAL HE STAINED SECTIONS AND IMMUNOHISTOCHEMICAL STAINS
FOR CYTOKERATINS (AEL:AE3 AND CAM 5.2) SHOW NO EVIDENCE OF
METASTATIC TUMOR.

** Report Electronically Signed Out **

ADDENDUM:

** SIGNED OUT **

ADDENDUM REPORT

SITE: BREAST, LEFT: MODIFIED RADICAL MASTECTOMY
PART #4.

ER-ICA: NEGATIVE

PR-ICA: NEGATIVE

HER2/NEU (HERCEPT): POSITIVE (STAINING INTENSITY OF 3+).
CONTROLS ARE SATISFACTORY.

ADDENDUM REPORT

** Continued on next page **

PATH
REPORT
11

[page 9 of 9]
SITE: BREAST, RIGHT, MODIFIED RADICAL MASTECTOMY
PART #9.

ER-ICA: NEGATIVE
PR-ICA: NEGATIVE
HER2/NEU (HERCEPTEST): NEGATIVE (STAINING INTENSITY OF 0).
CONTROLS ARE SATISFACTORY.

2/

** Report Electronically Signed Out **

** End of Report **

PATH
REPORT
11

Source: NCI Genomic Data Commons file 8ac2d9d3-64bc-48ff-bf76-81233171503e (TCGA-AO-A124.9009B4A7-3570-4AD6-878E-90CE8DA7980A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).